Somatic mutation profile of tumor specimen TCGA-20-0987-01A (aliquot TCGA-20-0987-01A-02W-0486-08) from TCGA case TCGA-20-0987, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,287 days).
Specimen TCGA-20-0987-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8704a45-7e46-4e14-b027-0b1a3507e354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-0987-10A (Blood Derived Normal), aliquot TCGA-20-0987-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ac1f058-ef7f-4ea4-8caa-e912f7963876

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 122/238 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.1292G>A p.W431* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as COSV99228199; called by muse, mutect2
- ARF6 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV53597226; called by muse, mutect2, varscan2
- BAHCC1 | c.7779G>T p.Q2593H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57023077; called by muse, mutect2, varscan2
- COL5A3 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV53406493; called by muse, mutect2, varscan2
- COLEC10 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769900711, COSV60520610; called by muse, mutect2, varscan2
- DUSP7 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 140/294 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs754356172, COSV56588625; called by muse, mutect2, varscan2
- FRMD7 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 148/640 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756203775, COSV53748308; called by muse, mutect2, varscan2
- FZD7 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as rs747123860, COSV53808341; called by muse, mutect2, varscan2
- GLYR1 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100424094; called by muse, mutect2, varscan2
- GTF3C4 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV64644973; called by muse, mutect2, varscan2
- HDAC3 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100539445, COSV100539764; called by muse, mutect2
- JPH1 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 251/589 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV60608766; called by muse, mutect2, varscan2
- MEGF8 | c.2713C>T p.R905W (on ENST00000251268 / NM_001271938.2; = p.R838W on NM_001410.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs375529059; called by muse, mutect2, varscan2
- MUC16 | c.20999C>G p.S7000C | Missense Mutation (SNP) | VAF 403/1111 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV67446548, COSV67487093; called by muse, mutect2, varscan2
- NODAL | c.194-1G>A p.X65_splice | Splice Site (SNP) | VAF 8/144 reads (6%) | catalogued as CS094514, COSV99755363; called by muse, mutect2
- PCDHGA2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53998896; called by muse, mutect2
- PPP6R1 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV69799285; called by muse, mutect2, varscan2
- RBM28 | c.1087T>G p.Y363D | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56161652; called by muse, mutect2, varscan2
- SFRP2 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56836828; called by muse, mutect2, varscan2
- SLC22A14 | c.1663del p.L555Sfs*17 | Frame Shift Del (DEL) | VAF 40/158 reads (25%) | catalogued as COSV56196689; called by mutect2, pindel, varscan2
- SPTB | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV67629876; called by muse, mutect2, varscan2
- STAG2 | c.3594+1G>T p.X1198_splice | Splice Site (SNP) | VAF 123/371 reads (33%) | catalogued as COSV54358138, COSV54373163; called by muse, mutect2, varscan2
- TMEM200A | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV51649376; called by muse, mutect2, varscan2
- USP12 | c.132T>C p.F44= | Splice Region (SNP) | VAF 33/119 reads (28%) | catalogued as COSV99997439; called by muse, mutect2, varscan2
- CDK12 | c.2782dup p.E928Gfs*27 | Frame Shift Ins (INS) | VAF 105/236 reads (44%) | called by mutect2, pindel, varscan2
- MYOF | c.2146dup p.T716Nfs*20 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- RFX5 | c.858_858+25del p.X286_splice | Splice Site (DEL) | VAF 24/124 reads (19%) | called by mutect2, pindel, varscan2
- SELENBP1 | c.1081_1127del p.V361Sfs*40 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by mutect2, pindel
- TOP2A | c.578_579dup p.W194Hfs*46 | Frame Shift Ins (INS) | VAF 506/1312 reads (39%) | called by pindel, varscan2
- CLCNKA | c.1987A>C p.R663= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV58890458; called by muse, mutect2, varscan2
- FAT1 | c.11838G>A p.L3946= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV101499130; called by muse, mutect2
- GGNBP2 | c.1974C>T p.F658= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, varscan2
- HADH | c.897G>A p.E299= | Silent (SNP) | VAF 135/695 reads (19%) | catalogued as rs757282614, COSV58847122; called by muse, mutect2, varscan2
- NOP56 | c.747G>A p.R249= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV61388880; called by muse, mutect2, varscan2
- PCLO | c.4542A>G p.E1514= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs1479310701, COSV61617137; called by muse, mutect2, varscan2
- SPEN | c.7602G>C p.L2534= | Silent (SNP) | VAF 422/1390 reads (30%) | catalogued as COSV65358104, COSV65361415; called by muse, varscan2
